Gene-level copy-number profile of tumor specimen TCGA-XF-A8HI-01A from TCGA case TCGA-XF-A8HI, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 57.7 years (21,059 days).
Specimen TCGA-XF-A8HI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6f300c94-3942-40df-b7d6-4298517ebe5b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A8HI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6de9f63-5daf-4e2a-9aed-67b05a15ff2d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 2,295; copy number 2: 54,634; copy number 3: 2,793; copy number 4: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A8HI-01A-11D-A38F-01): tumor purity 0.91, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,058,771–23,956,444, 69 genes (broad region; genes not listed).
- chr9:92,000,087–92,620,529, 27 genes (within-gene range 0–1): SPTLC1, AL391219.1, HSPE1P22, AL354751.3, MTATP6P29, MTCO3P29, MTND3P23, MTND4LP7, MTND4P15, AL354751.1, LINC00475, AL354751.2, BEND3P2, PRSS47, AL136097.2, IARS1, MIR3651, SNORA84, NOL8, CENPP, AL136097.1, OGN, OMD, ASPN, ECM2, MIR4670, AL157827.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,234. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
